Surgical pathology report (de-identified scan), TCGA case TCGA-VD-AA8R, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-AA8R-01A (Primary Tumor).

[page 1 of 4]
Department of Pathology HISTOPATHOLOGY		
Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]
Forename(s) [REDACTED]	DOB/Age [REDACTED] Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]	

This Copy For: [REDACTED]

SPECIMEN

LEFT GLOBE ENUCLEATION
Prognostic/diagnostic

CLINICAL DETAILS

Choroidal melanoma. No treatment.
See diagram. Measurements: 14.10 x 13.73 x (6.55)mm.

MACROSCOPIC DESCRIPTION

A fresh, intact, left globe.

Dimensions: Axial 24mm, Horizontal 24mm, Vertical 23mm

Cornea: Horizontal 12mm, Vertical 11.5mm

Optic nerve: flush.

On trans-illumination, a large shadow is seen inferiorly, approximately 15mm in maximum dimension.

Plane of section: vertical

Intraocular description:

On opening, a solitary pale dome shaped choroidal mass is seen, with possible ciliary body involvement.

Tumour size:

LBD 13mm. Height 9mm.

MICROSCOPY

Sections show a virtually amelanotic melanoma consisting predominantly of spindle cells however also including a minor epithelioid cell component up to 10%. The tumour occupies basically the choroid with focal extension to pars plana. Most of tumour cells are arranged in a fascicular pattern with nuclear palisading. In addition, there is focal cytoplasmic vacuolation in tumour cells producing a balloon cell appearance.

The number of mitosis is approximately 4/40 high power

*ICD-O-3
Melanoma, epithelioid & spindle cell
mixed 8770/3
Site: Choroid C69.3
705/30/14*

Reported:

Pathologist: [REDACTED]

Electronically Verified: [REDACTED]

[page 2 of 4]
Department of Pathology

Page 2 of 4

, HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED] [REDACTED]
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]
Unit No [REDACTED] [REDACTED]	Request Date [REDACTED]	

This Copy For: [REDACTED]

fields. Closed loops are not present in the planes of sections. The lymphocytic infiltrate within the tumour is minimal. Few scattered macrophages are present. Tumour necrosis is not seen. Bruch's membrane appears focally breached in one of the sections. There is no tumour extension through the sclera, optic nerve or vortex veins examined. Tumour cells are not seen at the resection margins.

Elsewhere, the cornea shows no significant abnormality. The anterior chamber angles are open and the anterior chamber is shallow. The iris shows no significant abnormality but the ciliary body appears atrophic with hyalinisation of ciliary processes. The lens shows cataractuous changes. Retina overlying the tumour is slightly atrophic.

DIAGNOSIS

Left eye, enucleation: Ciliochoroidal melanoma of mixed cell type.

COMMENT

Assessment of HSP27 expression on immunohistochemistry will follow. In addition, molecular genetic examination of DNA extracted from the tumour cells will be performed using multiplex-ligation dependent probe amplification (MLPA), looking at chromosomes 1, 3, 6 and 8. A supplementary report will follow in due course.

SUPPLEMENTARY REPORT (MLPA)

In the meantime, molecular genetic analysis of tumour DNA extracted from the fresh uveal melanoma tissue was performed using the technique termed multiplex ligation-dependent probe amplification (MLPA). These investigations were performed in the

The kit P027 from [REDACTED], which examines for gains or losses in 31 loci on chromosomes 1, 3, 6 and 8, was used. The DNA concentration was measured using [REDACTED] and the quality assessed using multiplex-PCR prior to the MLPA reaction.

Reported:

Pathologist: [REDACTED]

Electronically Verified: [REDACTED]

[page 3 of 4]
Department of Pathology

Page 3 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]
Unit No [REDACTED]	Request Date [REDACTED]	

This Copy For: [REDACTED]

The DNA concentration was high and of good quality on assessment. The MLPA reaction was run at least twice on differing occasions, resulting in similar results.

The results of the sequence analysis of the MLPA products is printed on a separate report. In summary, sequence analysis demonstrated:

normal chromosome 1p,
disomy 3,
borderline gains in chromosome 6
and normal chromosome 8.

Taken together, these molecular data would place the patient in the low risk group with respect to the development of metastatic melanoma. Consideration of clinical features of the tumour is, however, also required.

SUPPLEMENTARY REPORT -

Tumour cells express Melan-A and HSP 27 (score 2).

SUMMARY

SPECIMEN	2= Eye
TUMOUR PRESENT	Yes
TUMOUR TYPE	1= Melanoma
CELL TYPE	3= Mixed
CT LOOPS	1= No closed loops
NECROSIS	No
PIGMENTATION	No
LYMPHOCYTIC INFILTRATION	No
MITOTIC FREQUENCY	4/40 HPF
DIFFUSE MELANOMA	No
SPREAD	1= No

Reported:

Pathologist: [REDACTED]

Electronically Verified: [REDACTED]

[page 4 of 4]
Department of Pathology

Page 4 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]
Unit No [REDACTED]	Request Date [REDACTED]	

This Copy For: [REDACTED]

CLEARANCE 2= Adequate
HSP-27 POSITIVITY 2= 21-70%
LARGE DIAMETER 13 mm
THICKNESS 9 mm

Reported:

Pathologist: [REDACTED]

Electronically Verified: [REDACTED]

Source: NCI Genomic Data Commons file 081e429b-24f0-48b8-b6e1-b66e6f3b8808 (TCGA-VD-AA8R.17015647-C660-4661-B739-0A58A88FC1EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).